Surgical pathology report (de-identified scan), TCGA case TCGA-IB-7885, project TCGA-PAAD (Pancreatic Adenocarcinoma), tissue source site Alberta Health Services, specimen TCGA-IB-7885-01A (Primary Tumor).

[page 1 of 3]
Surgical Pathology Report

Accession Number:

Collected Date:

Pathologist:

Received Date/Time:

Specimen Description

- A. Gallbladder
- B. Node of Importance
- C. Whipple's specimen

Clinical Information

Cancer in the head of the pancreas with malignant-appearing structure of the common bile duct as well as a double duct sign.

Diagnosis

- A. Cholecystectomy:
- Chronic cholecystitis
- B. Node Of Importance:
- One lymph node negative for carcinoma (0/1)
- C. Pancreaticoduodenectomy (Whipple resection), Partial Pancreatectomy:
- Ductal adenocarcinoma
- Site: pancreatic head
- Size: 2.4 cm
- Grade 2
- Tumor invades retropancreatic soft tissue
- Margins uninvolved by invasive carcinoma
- Distance of invasive carcinoma from closest margin: 0.5 mm (nonperitonealized retropancreatic/uncinate margin)
- Lymph-vascular invasion identified

[page 2 of 3]
Surgical Pathology Report

Accession Number:

Collected Date:

Pathologist:

Received Date/Time:

- Perineural invasion identified
- Three out of 12 lymph nodes directly invaded by tumor (3/12)
- Pancreatic intraepithelial neoplasia (PanIN-2)
- Chronic pancreatitis

Gross Description

Received are specimens A to C. All requisitions and specimen containers are labelled with the patient's name. The cassettes and AP identifiers are labelled with the Surgical Number.

A. Gallbladder measuring 9.5 x 4.5 x 1.6 cm. The cystic duct is short. The gallbladder is closed. After opening, it is filled with green bile and no calculus. The wall thickness is 3 mm. The mucosa is smooth with yellow surface. The serosal surface is smooth. There is hilar lymph node identified. Representative sections submitted in A1.

B. Node of importance. One lymph node 2.5 cm in diameter, bisected in B1 and B2.

C. Whipple's specimen. Devitalization time starts at [REDACTED]. The specimen consists of a duodenum measuring 19.0 cm in length and 5.0 to 6.0 cm in circumference. There is a portion of gastric tissue 2.5 cm in length. The common bile duct measures 5.3 cm in length and 1.6 cm in circumference. At 1.7 cm distal from the ampulla of Vater, there is stenosis of the common bile duct. The pancreas measures 5.0 x 2.5 x 2.0 cm. The nonperitonealized uncinate inked margin is inked in blue. There is a second minor duodenal papilla in addition to the major duodenal papilla. Within the head of the pancreas, there is a not well-demarcated tumor measuring 2.4 x 2.0 cm. The tumor shows some cystic areas toward the minor duodenal papilla, and is otherwise solid yellow/white and seems to approach the retropancreatic margin grossly quite closely.

C1 common bile duct margin

C2 proximal gastric margin

[page 3 of 3]
Clinical Pathology Report

Accession Number:

Collected Date:

Pathologist:

Received Date/Time:

C3 distal intestinal margin
C4 minor duodenal papilla
C6-C10 ampulla of Vater perpendicular sections
C11 en face transverse section below C6-C10
C12-C13 tumor in relation to common bile duct
C14-C17 tumor in relation to nonperitonealized uncinate inked margin
Q18 pancreatic parenchyma margin
Q19 lymph nodes
C20 one lymph node bisected
C21 further pancreatic parenchyma from the head
C22 further ? lymph node
MKO/cr

Pathologist Comment

Due to an unexplained technical problem, no synoptic report could be assessed.

Source: NCI Genomic Data Commons file 4526d70a-9b84-46c6-a602-1ce2e7849779 (TCGA-IB-7885.29BB1247-7507-4C0D-984D-10956563C3E4.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).